Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4775, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4775-01A (Primary Tumor).

[page 1 of 2]
Clinical Diagnosis & History:

██████████ with left renal mass.

Specimens Submitted:

- 1: Kidney, left, partial nephrectomy:
- 2: Kidney, left, cyst excision:

DIAGNOSIS:

1. Kidney, left, partial nephrectomy::

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade II/IV

Tumor Size:

Greatest diameter is 2.9 cm.

Local Invasion (for renal cortical types):

Not Identified

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

2. Kidney, left, cyst excision::

Portion of kidney with benign cortical cyst.

[page 2 of 2]
Gross Description:

1) The specimen is received fresh for frozen section, labeled "Left Kidney Tumor (stitch marks deep margin)". It consists of a portion of kidney parenchyma measuring 5.5 x 4.0 x 2.8 cm. The attached suture indicates surgical margin of resection which is inked blue. Sectioning reveals a well-circumscribed, yellow-orange tumor measuring 2.9 x 1.6 x 1.5 cm. The tumor appears to be 0.2 cm from the inked surgical margin of resection grossly. Tumor appears to be well encapsulated and not violate the renal capsule. The specimen is serially sectioned and entirely submitted.

Summary of Sections:

FSC - frozen section control

TM - tumor

RS - rest of the specimen

2). The specimen is received in formalin labeled, "Portion of cyst wall left kidney", and consists of a 0.5 x 0.4 x 0.1 cm piece of pink-tan soft tissue which is entirely submitted.

Summary of sections:

U-undesigned

Summary of Sections:

Part 1: Kidney, left, partial nephrectomy:

Block	Sect. Site	PCs
1	fsc	1
4	rs	4
8	tm	8

Part 2: Kidney, left, cyst excision:

Block	Sect. Site	PCs
1	u	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1) FROZEN SECTION DIAGNOSIS: CONVENTIONAL (CLEAR CELL) RENAL CELL CARCINOMA, MARGIN FREE OF TUMOR.
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file 3a186276-19e1-469a-9d39-57824172630a (TCGA-BP-4775.B47EF11A-4FC3-41AC-8B65-C3CFA0531AB3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).